Gene-level copy-number profile of tumor specimen ALCH-B34L-TTP1-A from ALCHEMIST case ALCH-B34L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 49.9 years (18,220 days).
Specimen ALCH-B34L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7fa0890d-6b5d-4115-acce-d20c339fa149.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B34L-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/f1eae067-ab45-40f7-bf49-333a671ad965

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 9,241; copy number 2: 47,376; copy number 3: 1,876; copy number 4: 84; copy number 5: 62; copy number 6: 69; copy number 7: 77; copy number 8: 3; copy number 9: 1; copy number 10: 9; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:238,100,340–238,155,994, 3 genes: ESPNL, KLHL30, KLHL30-AS1.
- chr3:52,794,768–52,835,729, 4 genes (within-gene range 0–2): ITIH3, ITIH4, AC006254.1, ITIH4-AS1.
- chr4:2,059,327–2,069,089, 1 gene: NAT8L.
- chr4:2,088,718–2,090,617, 1 gene (within-gene range 0–3): AL136360.1.
- chr6:32,005,636–32,035,418, 4 genes (within-gene range 0–1): CYP21A1P, TNXA, STK19B, C4B.
- chr7:128,862,042–128,950,038, 5 genes (within-gene range 0–2): KCP, ATP6V1F, ATP6V1FNB, AC025594.1, IRF5.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr12:108,589,851–108,598,320, 1 gene: TMEM119.
- chr15:25,182,385–25,269,858, 43 genes (within-gene range 0–1): SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1, SNORD115-45, SNORD115-46, SNORD115-47, SNORD115-48.
- chr15:41,828,095–41,848,155, 2 genes (within-gene range 0–2): JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr15:78,759,206–78,811,464, 1 gene (within-gene range 0–1): ADAMTS7.
- chr17:18,943,999–18,944,073, 1 gene: AC090286.2.
- chr17:21,376,357–21,419,870, 1 gene: KCNJ12.
- chr17:41,717,742–41,734,644, 3 genes (within-gene range 0–2): HAP1, RNA5SP442, RN7SL399P.
- chr18:79,470,120–79,470,940, 1 gene (within-gene range 0–2): AC018445.1.
- chr19:4,969,113–5,153,598, 1 gene: KDM4B.
- chr19:5,178,119–5,178,464, 1 gene (within-gene range 0–1): AC022517.1.
- chr20:41,340,821–41,366,818, 2 genes: LPIN3, EMILIN3.
- chr21:36,699,115–36,749,917, 1 gene (within-gene range 0–2): SIM2.
- chr21:44,158,740–44,160,076, 1 gene: LINC01678.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 223 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,773,962–74,789,376, 1 gene, copy number 10: NCF1.
- chr16:28,700,294–28,772,807, 3 genes, copy number 7–11 (within-gene range 5–11): CDC37P1, AC145285.5, NPIPB9.
- chr20:52,192,159–55,075,140, 33 genes, copy number 6–10 (within-gene range 1–10): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4.
- chr20:57,599,695–61,940,617, 70 genes, copy number 6–7 (within-gene range 4–10) (broad region; genes not listed).
- chr20:61,738,219–63,936,031, 114 genes, copy number 5–7 (broad region; genes not listed).
- chr21:43,461,960–43,479,534, 1 gene, copy number 9 (within-gene range 4–9): LINC00313.
- chr21:44,133,610–44,210,114, 1 gene, copy number 5 (within-gene range 0–5): GATD3A.

Autosomal genes at a single copy (total copy number 1): 6,432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
